Gene-level copy-number profile of tumor specimen REBC-AF93-TTP1 from REBC case REBC-AF93, project REBC-THYR (Comprehensive genomic characterization of radiation-related papillary thyroid cancer in the Ukraine). Sex at birth: female; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland.
Specimen REBC-AF93-TTP1: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ac54468d-2b37-4a36-b5da-1cc33a08e9f0.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator REBC-AF93-NB1-SC217001 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,226 have no estimate.
https://portal.gdc.cancer.gov/files/c3c9c88b-3edf-4543-a9fc-b6090eecf34d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 272; copy number 2: 57,897; copy number 3: 204; copy number 4: 24.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 272. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
